Gene-level copy-number profile of tumor specimen TCGA-BL-A0C8-01B from TCGA case TCGA-BL-A0C8, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Dome of bladder; AJCC pathologic stage: Stage I; Age at diagnosis: 73.4 years (26,819 days).
Specimen TCGA-BL-A0C8-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.eb2dac21-d065-4679-b15f-ba5d6d014499.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BL-A0C8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 361 have no estimate.
https://portal.gdc.cancer.gov/files/0f3fcf1a-e9ad-48bd-9d8b-30407f3f8f4f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 7,680; copy number 2: 48,133; copy number 3: 4,074; copy number 4: 204; copy number 5: 40; copy number 6: 1; copy number 7: 37; copy number 8: 27; copy number 10: 24; copy number 11: 1; copy number 14: 31.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BL-A0C8-01A-11D-A273-01): tumor purity 0.59, ploidy 3.54, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:157,142,933–157,255,185, 3 genes (within-gene range 0–2): ITK, FAM71B, AC010609.1.
- chr9:5,584,490–5,588,994, 1 gene: AL162253.1.
- chr10:78,352,597–78,367,623, 2 genes (within-gene range 0–28): AC010163.2, SNORA71.
- chr19:47,994,632–48,025,154, 1 gene (within-gene range 0–2): ELSPBP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 142 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:9,671,875–9,770,341, 4 genes, copy number 5 (within-gene range 2–5): AC082651.4, RNU4-73P, AC082651.2, AC082651.3.
- chr2:88,857,161–89,117,844, 24 genes, copy number 5: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17.
- chr3:11,790,442–12,788,671, 24 genes, copy number 10: TAMM41, FANCD2P2, CYCSP12, NUP210P2, MARK2P14, AC090958.1, RN7SL147P, SYN2, ACTG1P12, TIMP4, MTCO1P5, GSTM5P1, PPARG, AC091492.1, TSEN2, RNA5SP123, RNU6-377P, MKRN2OS, MKRN2, Metazoa_SRP, RAF1, CRIP1P1, TMEM40, KRT18P17.
- chr3:45,676,369–46,580,099, 27 genes, copy number 8 (within-gene range 2–8): LIMD1-AS1, SACM1L, RN7SL145P, AC098476.1, SLC6A20, LZTFL1, AC099782.1, SDHDP4, CCR9, Y_RNA, FYCO1, CXCR6, XCR1, NRBF2P2, FLT1P1, CCR3, CCR1, UQCRC2P1, CCR2, CCR5AS, CCR5, CCRL2, LINC02009, LTF, RTP3, LRRC2, LRRC2-AS1.
- chr5:132,747,426–133,026,604, 18 genes, copy number 7 (within-gene range 3–7): CCNI2, SEPTIN8, SOWAHA, AC004775.1, SHROOM1, RNA5SP192, GDF9, UQCRQ, LEAP2, AFF4, AC010240.2, Y_RNA, ATP6V0E1P1, AC010240.3, AC010240.1, Y_RNA, ZCCHC10, AC113410.1.
- chr7:62,275,361–63,088,261, 5 genes, copy number 5: AC128676.1, RNU6-417P, AC069285.2, AC069285.3, ZNF90P3.
- chr8:101,337,496–101,492,499, 7 genes, copy number 5–11: AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1, AP001207.3.
- chr10:3,397,505–3,502,915, 2 genes, copy number 5 (within-gene range 2–5): AL356433.1, LINC02669.
- chr14:105,881,034–105,972,269, 31 genes, copy number 14: IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6.

Autosomal genes at a single copy (total copy number 1): 4,792. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
